CCDI case PBBNYH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/5691dc3b-1244-4380-be50-6adb59f84ff7

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Retinoblastoma, NOS: ICD-O-3 morphology code: 9510/3; Tissue or organ of origin: Retina; Age at diagnosis: 3.2 years (1,156 days).

Biospecimens (3 samples)
- Sample 0DEYDJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DEYDS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DEYEB: Tissue type: Tumor; Specimen type: Solid Tissue.
